Somatic mutation profile of tumor specimen MMRF_2562_1_BM_CD138pos (aliquot MMRF_2562_1_BM_CD138pos_T1_KHS5U_K15143) from MMRF case MMRF_2562, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.4 years (24,237 days).
Specimen MMRF_2562_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50f99e37-a73b-4306-8c49-d69f7e0c2dc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2562_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2562_1_PB_Whole_C3_KHS5U_K15142; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4daa9c7e-f5e1-4c2e-b2dd-3a990e997715

The open-access MAF lists 110 somatic variants for this specimen: 46 protein-altering or splice-affecting, 14 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 27, Silent 14, Intron 12, 5'UTR 5, Frame Shift Del 3, Splice Region 3, RNA 3, Nonsense Mutation 3, 5'Flank 2, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHCY | c.731T>C p.I244T | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.081); catalogued as rs372514895; called by muse, mutect2
- ASIC4 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as rs975816858, COSV61730967; called by muse, mutect2
- CLIP1 | c.2938G>T p.E980* (on ENST00000620786 / NM_001247997.1; = p.E969* on NM_002956.2) | Nonsense Mutation (SNP) | VAF 39/117 reads (33%) | catalogued as COSV56798657; called by muse, mutect2, varscan2
- CRIP1 | c.131C>G p.A44G | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as rs1555438465; called by muse, mutect2, varscan2
- CSMD3 | c.967C>G p.L323V | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV52132305, COSV52280424, COSV99827888; called by muse, mutect2, varscan2
- DCSTAMP | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 113/191 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775661354, COSV52576538; called by muse, varscan2
- EPHA5 | c.2049A>C p.A683= | Splice Region (SNP) | VAF 32/80 reads (40%) | catalogued as COSV56627934; called by muse, mutect2, varscan2
- FER1L6 | c.3403A>G p.I1135V | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV101205549; called by muse, mutect2, varscan2
- IFNA13 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs765854122; called by muse, mutect2, varscan2
- KIF1A | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 27/32 reads (84%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs549643552; called by muse, mutect2, varscan2
- KRT32 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs572300244; called by muse, mutect2, varscan2
- LENG8 | c.2030G>A p.G677E | Missense Mutation (SNP) | VAF 117/344 reads (34%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.971); catalogued as rs764370659; called by muse, mutect2, varscan2
- LTB | c.208+8C>T | Splice Region (SNP) | VAF 111/246 reads (45%) | catalogued as rs752684862, COSV59865114; called by muse, mutect2, varscan2
- MYH6 | c.2086C>T p.R696C | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs778886029, COSV62447797; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEB | c.19597C>T p.R6533W | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs373551215; ClinVar: uncertain significance; called by mutect2, varscan2
- SCN10A | c.4745G>A p.R1582H | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs759164988, COSV101479305, COSV71861815; called by muse, mutect2
- SEC14L6 | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 85/207 reads (41%) | catalogued as rs1214065963; called by muse, mutect2, varscan2
- ZNF285 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.202); catalogued as COSV58409634; called by muse, mutect2, varscan2
- ABR | c.501G>T p.Q167H (on ENST00000302538 / NM_021962.5; = p.Q130H on NM_001092.5) | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- ADAM10 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 7/173 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.018); called by muse, mutect2
- ARHGEF15 | c.2443A>T p.R815W | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BMP2K | c.1459C>T p.H487Y | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- BMP6 | c.1337_1365del p.S446Yfs*27 | Frame Shift Del (DEL) | VAF 68/196 reads (35%) | called by mutect2, pindel, varscan2
- CENPJ | c.1876A>C p.N626H | Missense Mutation (SNP) | VAF 48/59 reads (81%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSK | c.557-8C>T | Splice Region (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- DAXX | c.2083A>G p.T695A | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAH14 | c.8064G>C p.K2688N (on ENST00000445597; = p.K3491N on NM_001367479.1) | Missense Mutation (SNP) | VAF 179/247 reads (72%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- EIF2AK3 | c.2589_2593del p.L863Ffs*5 | Frame Shift Del (DEL) | VAF 47/161 reads (29%) | called by mutect2, pindel, varscan2
- EPHA5 | c.2048C>G p.A683G | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- ERP44 | c.1100_1116del p.T367Rfs*12 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- ESX1 | c.739C>A p.L247M | Missense Mutation (SNP) | VAF 77/81 reads (95%) | SIFT tolerated (0.13); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- F8 | c.2996G>A p.G999E | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FBXW8 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- H1-4 | c.496G>C p.G166R | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HNRNPA1 | c.530T>C p.V177A | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- LRP1 | c.8698C>T p.Q2900* | Nonsense Mutation (SNP) | VAF 5/107 reads (5%) | called by muse, mutect2
- LRRC7 | c.4505G>A p.G1502E (on ENST00000651989 / NM_001370785.2; = p.G1422E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLEK | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRPF8 | c.2134C>T p.H712Y | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPATA6L | c.613C>T p.L205F (on ENST00000461761 / NM_001353484.2; = p.L147F on NM_001039395.4 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.022); called by muse, mutect2
- TMBIM6 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- TNR | c.2141A>G p.D714G | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- TSPYL1 | c.1043T>A p.V348E | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- XDH | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 112/279 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ZNF235 | c.341G>A p.S114N | Missense Mutation (SNP) | VAF 58/237 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF44 | c.517G>T p.D173Y (on ENST00000356109 / NM_001164276.2; = p.D125Y on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 111/365 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- CNTN3 | c.2977C>A p.R993= | Silent (SNP) | VAF 22/329 reads (7%) | catalogued as COSV55162682; called by muse, mutect2
- CPA1 | c.972T>A p.P324= | Silent (SNP) | VAF 34/65 reads (52%) | called by muse, mutect2, varscan2
- DEGS2 | c.597C>T p.A199= | Silent (SNP) | VAF 49/135 reads (36%) | catalogued as rs766657505; called by muse, mutect2, varscan2
- H2BC5 | c.141G>A p.K47= | Silent (SNP) | VAF 85/183 reads (46%) | called by muse, mutect2, varscan2
- IGKJ4 | c.3C>T p.L1= | Silent (SNP) | VAF 42/84 reads (50%) | called by muse, varscan2
- LRRTM1 | c.288G>C p.L96= | Silent (SNP) | VAF 7/195 reads (4%) | called by muse, mutect2
- MYH2 | c.5001C>T p.L1667= | Silent (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- PANX3 | c.276G>A p.K92= | Silent (SNP) | VAF 84/165 reads (51%) | called by muse, mutect2, varscan2
- PIK3CD | c.1335C>T p.V445= | Silent (SNP) | VAF 80/143 reads (56%) | called by muse, mutect2, varscan2
- RBBP8NL | c.1356C>T p.G452= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as rs950066696; called by muse, mutect2
- ROPN1L | c.498G>A p.K166= | Silent (SNP) | VAF 163/188 reads (87%) | catalogued as COSV99928775; called by muse, mutect2, varscan2
- S1PR2 | c.243G>A p.L81= | Silent (SNP) | VAF 14/223 reads (6%) | catalogued as rs1350338751; called by muse, mutect2
- TLE1 | c.252A>G p.R84= | Silent (SNP) | VAF 42/42 reads (100%) | called by muse, mutect2, varscan2
- UTP25 | c.627T>C p.N209= | Silent (SNP) | VAF 58/241 reads (24%) | called by muse, mutect2, varscan2
- ABL2 | c.*1648A>G | 3'UTR (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- AC118942.1 | n.915T>A | RNA (SNP) | VAF 46/101 reads (46%) | called by muse, mutect2, varscan2
- ADAM32 | c.*61C>T | 3'UTR (SNP) | VAF 17/509 reads (3%) | called by muse, mutect2
- ALAD | c.*98C>G | 3'UTR (SNP) | VAF 73/170 reads (43%) | called by muse, mutect2, varscan2
- AMMECR1L | c.*2831C>T | 3'UTR (SNP) | VAF 6/90 reads (7%) | catalogued as rs1282608514, COSV99760974; called by muse, mutect2
- ARV1 | c.-3G>A | 5'UTR (SNP) | VAF 110/143 reads (77%) | called by muse, mutect2, varscan2
- C10orf67 | c.*1584G>A | 3'UTR (SNP) | VAF 15/27 reads (56%) | catalogued as rs181061552; called by muse, mutect2, varscan2
- C1orf226 | c.*378C>A | 3'UTR (SNP) | VAF 93/120 reads (78%) | called by muse, mutect2, varscan2
- CTBP2 | c.58+12715G>T | Intron (SNP) | VAF 43/111 reads (39%) | called by muse, mutect2, varscan2
- CYBB | c.*1738A>G | 3'UTR (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- DCAF5 | c.-114T>G | 5'UTR (SNP) | VAF 34/75 reads (45%) | called by muse, mutect2, varscan2
- DNAJC19 | c.-70G>A | 5'UTR (SNP) | VAF 102/300 reads (34%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.741+651T>A | Intron (SNP) | VAF 32/99 reads (32%) | called by muse, mutect2, varscan2
- ENAM | c.*366A>G | 3'UTR (SNP) | VAF 40/71 reads (56%) | called by muse, mutect2, varscan2
- ETV1 | c.181+217T>A | Intron (SNP) | VAF 12/240 reads (5%) | called by muse, mutect2
- GREM2 | c.*32G>A | 3'UTR (SNP) | VAF 44/55 reads (80%) | catalogued as COSV100547425; called by muse, mutect2, varscan2
- IKZF3 | c.*7113T>A | 3'UTR (SNP) | VAF 27/76 reads (36%) | called by muse, mutect2, varscan2
- JCHAIN | c.*595G>C | 3'UTR (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- LINC00898 | n.2671G>A | RNA (SNP) | VAF 56/106 reads (53%) | catalogued as rs570451963; called by muse, mutect2, varscan2
- LRRC75A | c.*1444G>A | 3'UTR (SNP) | VAF 50/117 reads (43%) | called by muse, mutect2, varscan2
- LTB | c.208+86A>C | Intron (SNP) | VAF 47/93 reads (51%) | called by muse, mutect2, varscan2
- LYZL2 | c.-41G>A | 5'UTR (SNP) | VAF 56/195 reads (29%) | catalogued as rs1395467509; called by muse, varscan2
- MCOLN1 | c.*95C>A | 3'UTR (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851324 C>T | 5'Flank (SNP) | VAF 82/156 reads (53%) | catalogued as rs572738324; called by muse, mutect2, varscan2
- OLFML3 | c.401-18C>G | Intron (SNP) | VAF 42/87 reads (48%) | called by muse, mutect2, varscan2
- PCNX2 | c.6241-45G>A | Intron (SNP) | VAF 60/267 reads (22%) | called by muse, mutect2, varscan2
- PIM1 | c.*240T>C | 3'UTR (SNP) | VAF 12/36 reads (33%) | called by mutect2, varscan2
- POU2AF1 | c.*1779T>C | 3'UTR (SNP) | VAF 57/85 reads (67%) | called by muse, mutect2, varscan2
- PPP1R3A | c.*355del | 3'UTR (DEL) | VAF 22/42 reads (52%) | catalogued as rs914567975; called by mutect2, varscan2
- PROSER2 | c.392-73T>C | Intron (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- RASGRF1 | c.*969A>G | 3'UTR (SNP) | VAF 33/113 reads (29%) | called by muse, mutect2, varscan2
- RGS7BP | c.*192_*194del | 3'UTR (DEL) | VAF 18/55 reads (33%) | called by mutect2, pindel, varscan2
- SEMA3A | c.-48T>A | 5'UTR (SNP) | VAF 100/239 reads (42%) | called by muse, mutect2, varscan2
- SH3RF3 | c.*2647G>A | 3'UTR (SNP) | VAF 13/38 reads (34%) | catalogued as rs1022615748; called by muse, mutect2, varscan2
- SIK1B | c.*402T>C | 3'UTR (SNP) | VAF 17/40 reads (43%) | catalogued as rs1206018930; called by muse, mutect2, varscan2
- SLC2A11 | c.121-2053C>G | Intron (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- SNX6 | c.*980G>A | 3'UTR (SNP) | VAF 55/280 reads (20%) | catalogued as rs1290465798; called by muse, mutect2, varscan2
- SOS1 | c.*1535G>A | 3'UTR (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.523-47T>G | Intron (SNP) | VAF 58/144 reads (40%) | called by muse, mutect2, varscan2
- SSPOP | n.9294C>T | RNA (SNP) | VAF 19/32 reads (59%) | called by muse, mutect2, varscan2
- STEAP2 | c.*1844T>C | 3'UTR (SNP) | VAF 41/81 reads (51%) | called by muse, mutect2, varscan2
- TAGLN2 | chr1:159918691 G>A | 3'Flank (SNP) | VAF 57/134 reads (43%) | called by muse, mutect2, varscan2
- TCF4 | c.369+2407T>G | Intron (SNP) | VAF 12/355 reads (3%) | called by muse, mutect2
- TMEM183A | c.*367T>A | 3'UTR (SNP) | VAF 20/23 reads (87%) | called by muse, mutect2, varscan2
- TTN | c.10303+2343T>C | Intron (SNP) | VAF 12/109 reads (11%) | catalogued as rs746788555; called by muse, mutect2, varscan2
- TWF1 | c.103+180A>C | Intron (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- UQCC3 | c.*1443C>A | 3'UTR (SNP) | VAF 32/49 reads (65%) | called by muse, mutect2, varscan2
- UVSSA | c.*9563G>A | 3'UTR (SNP) | VAF 6/64 reads (9%) | catalogued as rs1289180296; called by muse, varscan2
- ZDHHC21 | c.*336T>G | 3'UTR (SNP) | VAF 4/98 reads (4%) | called by muse, mutect2
- ZNF774 | chr15:90349118 T>C | 5'Flank (SNP) | VAF 127/220 reads (58%) | called by muse, mutect2, varscan2
